TCGA case TCGA-XF-A9T6 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6ee18b9a-3f45-491f-9535-502820cfcf46

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 88 years; Vital status: Alive.

Diagnoses (4)
1. Papillary transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8130/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 88.2 years (32,207 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension: Focal; Extracapsular extension present: Yes; Lymph nodes positive: 0; Lymph nodes tested: 48; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
2. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Upper limb, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 83.2 years (30,406 days); Days to diagnosis: -1,801 days (-4.9 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,801 days (-4.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Papillary transitional cell carcinoma: ICD-O-3 morphology code: 8130/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 87.8 years (32,081 days); Days to diagnosis: -126 days; AJCC pathologic T: T1.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -126 days; Treatment anatomic sites: Bladder.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS; Timepoint category: Prior to Procurement.

Follow-up (2 entries)
- Karnofsky performance status: 90.
- Follow-up contact recording only the day: day 64.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 157 cm; BMI: 29.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Occupation type: Other.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Pancreas Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-A9T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 620 mg.
  Slide TCGA-XF-A9T6-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XF-A9T6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-A9T6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Occupation current: home maker; Occupation primary: home maker; Occupation primary industry: home maker; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Transurethral resection alone.
- Follow-up form: Lost to follow-up: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Elbow; Other malignancy histological type: Melanoma.
- Other malignancy form 1, Surgery: Other malignancy surgery type: Resection.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy histological type: POORLY    DIFFERENTIATED PAPILLARY UROTHELIAL CARCINOMA, GRADES 3 AND 4/4.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Turbt.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 64 days; disease-specific survival: no event (censored), 64 days; progression-free interval: no event (censored), 64 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-A9T6-01A-11D-A42D-01): tumor purity 0.83, ploidy 2.09, whole-genome doublings 0.
